Gene-level copy-number profile of tumor specimen TCGA-24-1920-01A from TCGA case TCGA-24-1920, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.0 years (27,042 days).
Specimen TCGA-24-1920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e058bfd2-dc21-4951-98df-ee2ce1f579a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1920-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/33118722-772e-4ffd-b3e1-ab1ac34c5124

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 111; copy number 1: 1,942; copy number 2: 12,319; copy number 3: 22,552; copy number 4: 10,135; copy number 5: 6,234; copy number 6: 3,802; copy number 7: 1,237; copy number 8: 719; copy number 9: 278; copy number 10: 56; copy number 11: 152; copy number 12: 9; copy number 13: 74; copy number 15: 43; copy number 16: 25; copy number 17: 116.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:14,108,813–22,884,000, 111 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,709 genes in 52 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:54,225,432–56,645,301, 49 genes, copy number 7: SSBP3, SSBP3-AS1, AL161644.1, AL035415.1, AC099796.2, LINC02784, AC099796.1, HNRNPA1P63, ACOT11, FAM151A, AL590093.1, MROH7, MROH7-TTC4, TTC4, PARS2, TTC22, AC096536.1, LEXM, DHCR24, AC096536.3, AC096536.2, DHCR24-DT, AL590440.2, TMEM61, AL590440.1, BSND, PCSK9, USP24, MIR4422HG, GYG1P3, MIR4422, AL603840.1, GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA, LINC01755, LINC01753, PIGQP1, AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1.
- chr1:60,515,716–62,865,516, 32 genes, copy number 7: LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P, USP1, DOCK7, AL451044.1, ANGPTL3, AL138847.2, AL138847.1, AC103923.1, ATG4C.
- chr1:70,530,526–72,282,539, 16 genes, copy number 8 (within-gene range 6–8): CHORDC1P5, CASP3P1, LINC01788, AL513285.1, PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186, ZRANB2-AS2, AL358453.1, NEGR1, AL354949.1, AL359821.1, NEGR1-IT1.
- chr1:115,270,767–116,502,634, 31 genes, copy number 7: AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1, CASQ2, NHLH2, HNRNPA1P43, LINC01649, AL357137.1, SLC22A15, AL365318.1, MAB21L3, LINC01779, U3, AL355538.1, ATP1A1, ATP1A1-AS1, RNU6-817P, LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2.
- chr1:118,264,372–121,580,524, 81 genes, copy number 8–11 (broad region; genes not listed).
- chr1:171,248,471–175,148,075, 85 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:233,448,626–236,604,516, 91 genes, copy number 7 (broad region; genes not listed).
- chr1:242,082,986–242,524,697, 7 genes, copy number 7 (within-gene range 6–7): PLD5, AL591686.2, RN7SKP12, AL591686.1, AL360271.2, RPL10AP5, AL360271.1.
- chr2:53,532,672–56,386,172, 56 genes, copy number 8 (within-gene range 3–8): ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93.
- chr2:61,471,188–64,332,801, 62 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:68,822,855–74,893,359, 174 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr2:175,842,887–178,516,463, 79 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr3:107,220,744–111,665,750, 58 genes, copy number 7 (within-gene range 5–7): DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3, CD96, AC092916.1, ATP6V0CP2, AC092916.2, ZBED2, NT5C3AP2.
- chr3:160,227,454–184,457,891, 364 genes, copy number 7–17 (within-gene range 6–17) (broad region; genes not listed).
- chr3:187,668,912–188,003,990, 10 genes, copy number 10: SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2.
- chr3:188,562,238–191,398,659, 29 genes, copy number 7: LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50.
- chr3:193,241,128–193,697,811, 9 genes, copy number 9: PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA.
- chr4:13,051,342–13,648,400, 11 genes, copy number 7: U6, HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1.
- chr6:9,596,110–11,382,348, 42 genes, copy number 15 (within-gene range 4–15): OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1.
- chr6:17,224,243–18,674,001, 27 genes, copy number 10: AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1.
- chr6:85,949,690–88,442,928, 48 genes, copy number 8: AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P, AL353133.1, AL353133.2, AL157777.1, AL157777.2, HTR1E, RPL7P29, MTHFD2P2, AL138827.1, RN7SKP209, CGA, RCN1P1, AL139274.2, ZNF292, AL139274.1, GJB7, HSPD1P10, SMIM8, C6orf163, AL096817.1, CFAP206, AL049697.1, AL049697.2, AL049697.3, ST13P16, SLC35A1, RNU6-444P, RARS2, ORC3, AKIRIN2, AL133211.1, Y_RNA, RN7SL183P, AL590392.1, AL136096.1, SPACA1, CNR1, AL121835.2, AL139042.1, AL121835.1, ACTBP8, AL139090.1.
- chr6:142,748,443–154,246,867, 198 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr6:160,702,238–165,309,605, 42 genes, copy number 8: PLG, AL109933.5, AL109933.4, AL109933.3, AL391361.2, AL391361.1, AL139393.2, AL139393.1, MAP3K4-AS1, MAP3K4, AGPAT4, PRKN, AL132982.1, AL138716.1, KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P, AL136225.1, Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1, AL450345.2, AL450345.1, AL133538.1, AL136100.1, C6orf118.
- chr7:100,928,370–104,907,232, 100 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr7:105,110,704–109,764,357, 71 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr7:112,206,695–112,995,677, 17 genes, copy number 9 (within-gene range 5–9): ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17.
- chr7:148,876,018–152,465,549, 127 genes, copy number 7 (broad region; genes not listed).
- chr8:124,539,101–131,432,869, 95 genes, copy number 7–11 (broad region; genes not listed).
- chr8:133,946,677–137,092,183, 28 genes, copy number 7 (within-gene range 5–7): AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1.
- chr9:4,944,670–7,175,648, 60 genes, copy number 7: HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1.
- chr10:4,497,449–4,515,244, 2 genes, copy number 9: AC022535.2, RNU6-163P.
- chr10:21,028,999–21,394,592, 8 genes, copy number 7: EIF4BP2, NPM1P30, NEBL-AS1, AL731547.1, LUZP4P1, RNU6-15P, LINC02643, RNMTL1P1.
- chr12:19,445,949–22,690,665, 51 genes, copy number 7–8: RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1.
- chr12:22,722,229–22,743,091, 2 genes, copy number 7: RPS27P22, AC084819.1.
- chr12:37,575,587–41,700,251, 46 genes, copy number 7: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24.
- chr12:68,674,371–69,959,097, 36 genes, copy number 9: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr14:83,750,384–84,740,052, 8 genes, copy number 7: RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P.
- chr19:9,523,223–13,633,025, 249 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:45,091,214–51,023,107, 193 genes, copy number 8 (broad region; genes not listed).
- chr22:37,988,794–38,043,920, 3 genes, copy number 10: MIR4534, AL031587.1, AL031587.4.

Autosomal genes at a single copy (total copy number 1): 1,942. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
